Somatic mutation profile of tumor specimen CPT008924 (aliquot CPT008924-0002) from CPTAC case 01BR008, project CPTAC-2 (Breast). Tissue or organ of origin: Breast, NOS.
Specimen CPT008924: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27e133eb-9012-45d3-95bc-c99c3f39e13d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT008538 (Blood Derived Normal), aliquot CPT008538-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8932bd2c-1949-4611-b598-2d37b072ed48

The open-access MAF lists 88 somatic variants for this specimen: 53 protein-altering or splice-affecting, 27 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 27, Intron 5, Nonsense Mutation 4, Splice Region 3, 3'UTR 1, Splice Site 1, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEGF10 | c.2104+1G>A p.X702_splice | Splice Site (SNP) | VAF 16/122 reads (13%) | catalogued as rs1298663120, COSV57255045, COSV99175528; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 148/771 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ABCF1 | c.1237G>C p.E413Q (on ENST00000326195 / NM_001025091.2; = p.E375Q on NM_001090.3) | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as COSV58228875; called by muse, mutect2
- C5orf38 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as rs1429676093; called by muse, mutect2
- CCDC166 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 62/433 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV72638713; called by muse, mutect2, varscan2
- CHMP1A | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 78/805 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV53682775; called by muse, mutect2
- COL2A1 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 48/496 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1417502139, COSV61531175; called by muse, mutect2
- COQ8A | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 37/546 reads (7%) | catalogued as rs1195283118, COSV62010468; called by muse, mutect2
- CYBC1 | c.480C>A p.F160L | Missense Mutation (SNP) | VAF 166/743 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60065435; called by muse, varscan2
- FZD10 | c.838del p.R280Afs*85 | Frame Shift Del (DEL) | VAF 88/637 reads (14%) | catalogued as COSV57472900; called by mutect2, pindel, varscan2
- GIMAP1 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs748312037, COSV56187760; called by muse, mutect2, varscan2
- INSR | c.2429C>G p.S810C | Missense Mutation (SNP) | VAF 59/685 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV57161961; called by muse, mutect2
- LONRF3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV59151184; called by muse, varscan2
- MYH9 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 45/586 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53393275; called by muse, mutect2
- OR2L8 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 73/468 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV61728408; called by mutect2, varscan2
- PIGR | c.77A>G p.E26G | Missense Mutation (SNP) | VAF 121/477 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1332891904; called by muse, mutect2, varscan2
- PRICKLE3 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 17/368 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs782215533, COSV66234335; called by muse, mutect2
- RARS1 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV51565505; called by muse, mutect2
- SENP6 | c.2171G>C p.R724T | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100894305; called by muse, mutect2
- SLC22A4 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 54/507 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs141478353; called by muse, mutect2, varscan2
- TRIM66 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55125872; called by muse, mutect2, varscan2
- YY1 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 26/269 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs1464236898, COSV51764834; called by muse, mutect2
- ZBTB21 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 86/582 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV60404570; called by muse, mutect2, varscan2
- ZHX2 | c.1593G>C p.Q531H | Missense Mutation (SNP) | VAF 58/584 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV58715213; called by muse, mutect2
- ZNF280B | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs368642212, COSV100840346, COSV64529815; called by muse, mutect2
- ZNF672 | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 74/1149 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1350372457; called by muse, mutect2
- ABHD16B | c.197C>A p.T66K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.013); called by muse, mutect2
- BRIP1 | c.3008C>G p.S1003* | Nonsense Mutation (SNP) | VAF 25/154 reads (16%) | called by muse, mutect2, varscan2
- C16orf86 | c.477dup p.K160Qfs*44 | Frame Shift Ins (INS) | VAF 26/290 reads (9%) | called by mutect2, pindel
- CLIP2 | c.357G>C p.K119N | Missense Mutation (SNP) | VAF 108/1023 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CYBC1 | c.86-8C>T | Splice Region (SNP) | VAF 72/325 reads (22%) | called by muse, mutect2, varscan2
- DCLRE1C | c.1054G>T p.V352F (on ENST00000378278 / NM_001350965.2; = p.V237F on NM_022487.4) | Missense Mutation (SNP) | VAF 31/313 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DDX42 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 100/562 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by mutect2, varscan2
- FAT4 | c.4856T>C p.I1619T | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2
- FMO3 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GGA3 | c.802G>A p.E268K (on ENST00000537686 / NM_138619.4; = p.E235K on NM_014001.5) | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- HNRNPF | c.452T>A p.I151N | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- HPN | c.161-7C>G | Splice Region (SNP) | VAF 38/420 reads (9%) | called by muse, mutect2
- KIAA1958 | c.1079C>G p.S360* | Nonsense Mutation (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- NPAP1 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PHIP | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.237); called by muse, mutect2
- PLEKHG4B | c.1101C>G p.F367L (on ENST00000283426; = p.F723L on NM_052909.5) | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- PNPLA3 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POM121 | c.3445C>G p.Q1149E (on ENST00000434423; = p.Q884E on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/762 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- PPP1R12B | c.699C>T p.L233= | Splice Region (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- RBM17 | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.527); called by muse, mutect2
- TRAIP | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2
- TRAV41 | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- TRIM66 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- TRIM66 | c.2536G>C p.E846Q | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2
- TRPA1 | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 44/695 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- ZIC2 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZNF410 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- AC098582.1 | c.771C>G p.L257= | Silent (SNP) | VAF 17/196 reads (9%) | called by muse, mutect2
- BAHCC1 | c.657C>T p.L219= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as rs782116373, COSV57030429; called by muse, mutect2
- CARS1 | c.2229G>A p.Q743= | Silent (SNP) | VAF 34/316 reads (11%) | called by muse, mutect2, varscan2
- CD8A | c.27C>G p.L9= | Silent (SNP) | VAF 27/418 reads (6%) | called by muse, mutect2
- CNTRL | c.6786A>G p.V2262= | Silent (SNP) | VAF 60/463 reads (13%) | called by muse, mutect2, varscan2
- COL5A3 | c.3087C>T p.S1029= | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as rs373645845; called by muse, mutect2
- CPSF1 | c.1917C>T p.P639= | Silent (SNP) | VAF 19/219 reads (9%) | catalogued as rs782051707, COSV58233476; called by muse, mutect2
- FAM131B | c.420C>T p.L140= | Silent (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- FAM20A | c.198G>A p.T66= | Silent (SNP) | VAF 45/391 reads (12%) | called by muse, mutect2, varscan2
- FOXA3 | c.249C>T p.V83= | Silent (SNP) | VAF 29/260 reads (11%) | called by muse, mutect2, varscan2
- IGHG4 | c.669C>A p.P223= | Silent (SNP) | VAF 61/528 reads (12%) | called by mutect2, varscan2
- NABP2 | c.351C>G p.T117= | Silent (SNP) | VAF 30/518 reads (6%) | called by muse, mutect2
- NIN | c.4881C>T p.N1627= (on ENST00000382041 / NM_182946.1; = p.N914= on NM_016350.4) | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- OBSCN | c.276C>T p.F92= | Silent (SNP) | VAF 22/541 reads (4%) | called by muse, mutect2
- PLK3 | c.189C>G p.L63= | Silent (SNP) | VAF 20/292 reads (7%) | catalogued as rs955687172; called by muse, mutect2
- PLSCR4 | c.231T>C p.G77= | Silent (SNP) | VAF 50/475 reads (11%) | called by muse, mutect2, varscan2
- PPP4C | c.234C>T p.L78= | Silent (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- RUNX3 | c.321G>T p.V107= | Silent (SNP) | VAF 36/304 reads (12%) | called by mutect2, varscan2
- SLC1A6 | c.600G>A p.T200= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as rs371776048; called by muse, mutect2
- SLC51A | c.1014C>G p.L338= | Silent (SNP) | VAF 32/223 reads (14%) | catalogued as COSV99492410; called by muse, mutect2, varscan2
- SLC7A14 | c.1809G>T p.L603= | Silent (SNP) | VAF 36/264 reads (14%) | called by mutect2, varscan2
- SPTBN2 | c.5283C>T p.L1761= | Silent (SNP) | VAF 68/676 reads (10%) | catalogued as rs1214866445; called by muse, mutect2
- TBRG4 | c.531G>A p.R177= | Silent (SNP) | VAF 58/876 reads (7%) | called by muse, mutect2
- TENT4A | c.834G>A p.T278= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs145475863; called by muse, mutect2, varscan2
- UBE2K | c.12C>T p.I4= | Silent (SNP) | VAF 28/266 reads (11%) | called by muse, mutect2, varscan2
- XXYLT1 | c.687G>A p.L229= | Silent (SNP) | VAF 18/243 reads (7%) | catalogued as rs1172785773; called by muse, mutect2
- ZSWIM3 | c.537G>A p.K179= | Silent (SNP) | VAF 26/578 reads (4%) | called by muse, mutect2
- FIS1 | c.45+51G>C | Intron (SNP) | VAF 26/290 reads (9%) | called by muse, mutect2
- GHR | c.136+18599G>A | Intron (SNP) | VAF 7/58 reads (12%) | catalogued as rs1303105160; called by muse, mutect2, varscan2
- KAT6B | c.3664+33G>C | Intron (SNP) | VAF 16/238 reads (7%) | catalogued as rs1038407488; called by muse, mutect2
- SCP2D1 | chr20:18809923 C>T | 5'Flank (SNP) | VAF 40/404 reads (10%) | called by muse, mutect2
- STAC3 | c.-147G>A | 5'UTR (SNP) | VAF 25/154 reads (16%) | catalogued as rs1240507187; called by muse, mutect2, varscan2
- STX1A | c.540+262C>T | Intron (SNP) | VAF 29/241 reads (12%) | called by muse, mutect2, varscan2
- TMA7 | c.*28G>A | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- TRAPPC12 | c.1047+1060A>G | Intron (SNP) | VAF 28/352 reads (8%) | called by muse, mutect2
